TARGET case TARGET-40-NAAHAB — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/81b3d49b-e523-5431-a42e-922f334bfb54

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 9 years; Vital status: Dead; Days to death: 1,520 days (4.2 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.0; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 9.7 years (3,528 days); Year of diagnosis: 2010; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 1,520 days (4.2 years); Sites of involvement: Bone, NOS.
   Treatment given: Protocol identifier: GLATO 2006.
   Treatment given: Therapeutic agents: Cisplatin.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Methotrexate.

Follow-up (3 entries)
- Days to follow up: 573 days (1.6 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 573 days (1.6 years).
- Days to follow up: 1,005 days (2.8 years); Days to first event: 1,005 days (2.8 years); First event: Relapse.
- Days to follow up: 1,520 days (4.2 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2014.

Biospecimens (1 sample)
- Sample TARGET-40-NAAHAB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAHAB-01A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 70
- % Non Tumor Nuclei: Top from Biopsy: 30
- % Cellular Tumor: Top from Biopsy: 40
- % Normal: Top from Biopsy: 0
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 60
- % Tumor Nuclei: Bottom from Biopsy: 70
- % Non Tumor Nuclei: Bottom from Biopsy: 30
- % Cellular Tumor: Bottom from Biopsy: 30
- % Normal: Bottom from Biopsy: 0
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 70
- PASS/FAIL: fail (>50%NC)

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1520
- Disease at diagnosis: Metastatic
- Metastasis site: Bone
- Primary tumor site: Arm/Hand
- Specific tumor site: Humerus
- Specific tumor region: Proximal
- Definitive Surgery: Limb sparing
- Primary site progression: Yes
- Site of initial relapse: Lung
- Time to first relapse in days: 573
- Time to first enrollment on relapse protocol in days: 947
- Time to first SMN in days: 0
- Histologic response: Stage 1/2 (0-90 % necrosis)
- Relapse Type: Systemic, Locally recurrent
- Therapy: CIS+DOX+MTX
